Somatic mutation profile of tumor specimen 0DFO17 from CCDI case PBBSEY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,747 days).
Specimen 0DFO17: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3787dbf-1019-48ee-a876-9728d64ab354.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFO14 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1539ce0a-771e-4e71-bd3a-4ab6bd7daa3e

The open-access MAF lists 21 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, 5'UTR 2, Splice Site 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF9 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 38/1122 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1556335112; called by muse, mutect2
- FLG | c.3100G>A p.G1034R | Missense Mutation (SNP) | VAF 143/685 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs780634554, COSV64243291, COSV64246746; called by muse, mutect2, varscan2
- HSD3B1 | c.697C>A p.H233N | Missense Mutation (SNP) | VAF 132/631 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52491059, COSV52491915; called by muse, mutect2, varscan2
- RYR2 | c.14527C>T p.R4843* | Nonsense Mutation (SNP) | VAF 106/553 reads (19%) | catalogued as COSV63672574; called by muse, mutect2, varscan2
- TTN | c.33055C>T p.R11019C (on ENST00000591111; = p.R10092C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 134/564 reads (24%) | PolyPhen benign (0.172); catalogued as rs763380355, COSV59956834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF789 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 116/1076 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV58875013; called by muse, mutect2, varscan2
- AGER | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 126/778 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 46/1357 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- KCNN3 | c.1746+1G>A p.X582_splice (on ENST00000618040 / NM_001204087.1; = p.X567_splice on NM_002249.6) | Splice Site (SNP) | VAF 77/419 reads (18%) | called by muse, mutect2, varscan2
- NPAS1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR1A1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 127/677 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- OR1L3 | c.722G>T p.C241F | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- POLI | c.1773C>G p.S591R | Missense Mutation (SNP) | VAF 26/584 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); called by muse, mutect2
- ZNF789 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 136/720 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LHX1 | c.801G>A p.P267= | Silent (SNP) | VAF 94/675 reads (14%) | called by muse, mutect2, varscan2
- NEIL3 | c.621T>C p.A207= | Silent (SNP) | VAF 18/360 reads (5%) | called by muse, mutect2
- SATB2 | c.1893C>T p.S631= | Silent (SNP) | VAF 23/569 reads (4%) | called by muse, mutect2
- TLR10 | c.1044G>A p.T348= | Silent (SNP) | VAF 197/755 reads (26%) | catalogued as rs943886739, COSV58299785, COSV58300685; called by muse, mutect2, varscan2
- AKAP4 | c.-63G>T | 5'UTR (SNP) | VAF 23/205 reads (11%) | called by muse, mutect2, varscan2
- ALB | c.843+49T>A | Intron (SNP) | VAF 192/232 reads (83%) | called by muse, mutect2, varscan2
- STK17A | c.-32A>C | 5'UTR (SNP) | VAF 32/152 reads (21%) | called by muse, varscan2
